Somatic mutation profile of tumor specimen TCGA-OR-A5K2-01A (aliquot TCGA-OR-A5K2-01A-11D-A29I-10) from TCGA case TCGA-OR-A5K2, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 32.8 years (11,970 days).
Specimen TCGA-OR-A5K2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32fbdb88-89ba-44c6-bd93-f9171bd2c98b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5K2-10B (Blood Derived Normal), aliquot TCGA-OR-A5K2-10B-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f6642ba-3d5f-4e00-ba9a-21a0f79c7d14

The open-access MAF lists 55 somatic variants for this specimen: 37 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 16, Splice Site 2, Intron 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TPSD1 | c.65C>G p.P22R | Missense Mutation (SNP) | VAF 12/123 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as rs3865205, COSV52973780; called by muse, mutect2
- CDH23 | c.3029G>A p.R1010H | Missense Mutation (SNP) | VAF 120/540 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs370107953; called by muse, mutect2, varscan2
- CNTNAP5 | c.3497C>G p.S1166C | Missense Mutation (SNP) | VAF 68/148 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101443560; called by muse, mutect2, varscan2
- DGAT2L6 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60718744; called by muse, mutect2, varscan2
- DLGAP3 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); catalogued as rs140339373, COSV52395991, COSV52397212; called by muse, mutect2, varscan2
- JUP | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 29/339 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1555598694; called by muse, mutect2
- MSR1 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs867412653; called by muse, mutect2, varscan2
- ODF3B | c.450G>C p.L150F | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as rs752906913, COSV99329746; called by muse, mutect2, varscan2
- PIWIL3 | c.2587G>A p.V863M | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1310259628; called by muse, mutect2, varscan2
- POLE | c.1370C>G p.T457R | Missense Mutation (SNP) | VAF 52/275 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.401); catalogued as COSV57678756; called by muse, mutect2, varscan2
- SLC9A8 | c.1080_1081del p.F363Cfs*9 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | catalogued as rs762979646; called by mutect2, pindel, varscan2
- ZNF676 | c.1859C>T p.P620L (on ENST00000650058; = p.P588L on NM_001001411.3) | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV68093170, COSV68093462; called by muse, mutect2, varscan2
- ACTG1 | c.730G>C p.D244H | Missense Mutation (SNP) | VAF 82/343 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- AHNAK2 | c.8437T>C p.F2813L | Missense Mutation (SNP) | VAF 85/360 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- APBA2 | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 58/273 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ATP1A3 | c.1073A>C p.N358T (on ENST00000545399 / NM_001256214.2; = p.N345T on NM_152296.5) | Missense Mutation (SNP) | VAF 28/544 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- CATSPERG | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.028); called by muse, mutect2
- CDC7 | c.847C>A p.Q283K | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- CLSTN2 | c.1973T>C p.L658P | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CNTN5 | c.1420A>C p.K474Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- CTLA4 | c.449A>G p.Y150C | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DNAH3 | c.4456del p.I1486Sfs*3 | Frame Shift Del (DEL) | VAF 12/86 reads (14%) | called by mutect2, pindel, varscan2
- EEF1A1 | c.772_772+2del p.X258_splice | Splice Site (DEL) | VAF 41/153 reads (27%) | called by pindel, varscan2
- GOLGA4 | c.6473-2A>T p.X2158_splice | Splice Site (SNP) | VAF 11/57 reads (19%) | called by muse, mutect2, varscan2
- HSD11B1 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 69/192 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- IAPP | c.31A>C p.I11L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- METTL7B | c.365T>A p.F122Y | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MICAL3 | c.5450G>A p.R1817K | Missense Mutation (SNP) | VAF 66/234 reads (28%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MICAL3 | c.3482C>T p.P1161L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCNX2 | c.5909C>T p.S1970F | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2
- RPS6KA6 | c.914G>T p.R305M | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- SCN8A | c.2614G>T p.V872L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SGSM2 | c.1145G>C p.W382S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.357); called by muse, mutect2
- SLIT2 | c.365T>C p.L122P | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- SUPT6H | c.3943G>C p.D1315H | Missense Mutation (SNP) | VAF 69/178 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); called by muse, mutect2, varscan2
- TRIM38 | c.265C>G p.Q89E | Missense Mutation (SNP) | VAF 52/266 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZFAT | c.569G>T p.R190I | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- ABCA7 | c.2529C>T p.N843= | Silent (SNP) | VAF 43/90 reads (48%) | catalogued as rs760268060; called by muse, varscan2
- APOA2 | c.81G>A p.E27= | Silent (SNP) | VAF 48/144 reads (33%) | catalogued as rs557256114; called by muse, mutect2, varscan2
- ARID4B | c.3222T>G p.V1074= | Silent (SNP) | VAF 22/79 reads (28%) | called by muse, mutect2, varscan2
- ATP2B1 | c.1272T>A p.V424= | Silent (SNP) | VAF 61/255 reads (24%) | called by muse, mutect2, varscan2
- ATP2B2 | c.15C>G p.T5= | Silent (SNP) | VAF 40/130 reads (31%) | called by muse, mutect2, varscan2
- C1orf141 | c.171C>G p.S57= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV63993429; called by muse, mutect2, varscan2
- CALD1 | c.2184A>G p.A728= (on ENST00000361675 / NM_033138.4; = p.A473= on NM_004342.7) | Silent (SNP) | VAF 40/198 reads (20%) | called by muse, mutect2, varscan2
- CCR3 | c.717G>C p.R239= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV62463165; called by muse, mutect2, varscan2
- FBP2 | c.141G>A p.S47= | Silent (SNP) | VAF 40/281 reads (14%) | catalogued as rs370129734; called by muse, mutect2, varscan2
- FLNB | c.5196C>G p.A1732= | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as rs1425159521, COSV55898757; called by muse, mutect2, varscan2
- IPCEF1 | c.516T>A p.A172= | Silent (SNP) | VAF 12/139 reads (9%) | called by muse, mutect2
- KLK12 | c.627C>A p.V209= | Silent (SNP) | VAF 35/79 reads (44%) | called by muse, mutect2, varscan2
- KRT17 | c.258C>A p.A86= | Silent (SNP) | VAF 21/366 reads (6%) | called by muse, mutect2
- PDE1B | c.907T>C p.L303= | Silent (SNP) | VAF 60/300 reads (20%) | catalogued as rs768753473; called by muse, mutect2, varscan2
- SIRPB2 | c.987A>T p.A329= | Silent (SNP) | VAF 55/196 reads (28%) | called by muse, mutect2, varscan2
- ZNF765 | c.1476A>G p.K492= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as COSV67182210; called by muse, mutect2, varscan2
- FMN1 | c.2044-1503G>C | Intron (SNP) | VAF 28/103 reads (27%) | called by muse, mutect2, varscan2
- KAT5 | c.12+18G>A | Intron (SNP) | VAF 29/73 reads (40%) | called by muse, mutect2, varscan2
